Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5L1, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5L1-01A (Primary Tumor).

ICD0-3

Carcinoma, adrenal cortical
8370/3

Site: ① Adrenal Gland
Cortex C74.0

gn 2/6/13

Procedure: most likely L adrenalectomy and nephrectomy

Gross description: 9 x 8 x 4cm, 185.2g

Diagnosis: adrenocortical carcinoma

Reference Pathology:

Diagnosis: adrenocortical carcinoma, KI67 30%

Weiss score: 5

Hough score: 4.5

Van Slooten score: 14.7

Criteria	hw 1/16/13	Yes	No

Source: NCI Genomic Data Commons file 979dd53f-6d0e-4987-82ad-5176daf5f6cf (TCGA-OR-A5L1.914A8783-5ACF-4580-A663-E73BDDAA7286.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).